Somatic mutation profile of tumor specimen TARGET-15-SJMPAL041118-09A.2 (aliquot TARGET-15-SJMPAL041118-09A.2-01D) from TARGET case TARGET-15-SJMPAL041118, project TARGET-ALL-P3 (Acute Lymphoblastic Leukemia - Phase III). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 9.0 years (3,295 days).
Specimen TARGET-15-SJMPAL041118-09A.2: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cf436e89-8549-49c3-a5ab-a6765aecebc2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-15-SJMPAL041118-14A (Bone Marrow Normal), aliquot TARGET-15-SJMPAL041118-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f19b313c-076b-4570-bc52-acd802bdcdea

The open-access MAF lists 21 somatic variants for this specimen: 16 protein-altering or splice-affecting, 3 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 14, Silent 3, Splice Region 2, Intron 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.173C>T p.T58I | Missense Mutation (SNP) | VAF 10/91 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs104894364, CM061079, COSV55527371, COSV99800760; ClinVar: pathogenic; called by muse, mutect2, varscan2
- NRAS | c.37G>C p.G13R | Missense Mutation (SNP) | VAF 40/206 reads (19%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs121434595, COSV54736386, COSV54736476, COSV54736550; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- GALNT9 | c.800G>A p.R267H | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.765); catalogued as rs556119200; called by muse, mutect2, varscan2
- GLUD1 | c.187G>T p.D63Y | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV53280422; called by muse, mutect2, varscan2
- MMP16 | c.1097G>T p.W366L | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV54164647; called by muse, varscan2
- PCDH10 | c.1334C>A p.T445N | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.401); catalogued as COSV52100694; called by muse, mutect2, varscan2
- UNC80 | c.2027C>T p.A676V | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT tolerated (0.8); PolyPhen benign (0.187); catalogued as rs768146438; called by muse, mutect2, varscan2
- BAZ2B | c.631A>C p.K211Q | Missense Mutation (SNP) | VAF 36/68 reads (53%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.598); called by muse, mutect2, varscan2
- COL4A2 | c.1958C>A p.A653E | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- GDAP1L1 | c.546C>A p.R182= | Splice Region (SNP) | VAF 4/14 reads (29%) | called by mutect2, varscan2
- MUC17 | c.1270G>A p.V424M | Missense Mutation (SNP) | VAF 23/157 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.437); called by muse, mutect2, varscan2
- PCDHGA7 | c.724T>A p.F242I | Missense Mutation (SNP) | VAF 18/100 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.831); called by muse, mutect2, varscan2
- POLR1G | c.843C>A p.D281E | Missense Mutation (SNP) | VAF 5/81 reads (6%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- POLR1G | c.1222C>A p.L408M | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.031); called by mutect2, varscan2
- RASSF4 | c.533C>A p.T178N | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- SETD2 | c.5278_5290delinsCGGA p.N1760_Q1764delinsRK | Splice Region (DEL) | VAF 21/93 reads (23%) | called by pindel, varscan2*
- ADCY10 | c.3435C>T p.G1145= | Silent (SNP) | VAF 39/123 reads (32%) | called by muse, mutect2, varscan2
- IGHV4-59 | c.350A>T p.*117= | Silent (SNP) | VAF 5/110 reads (5%) | called by muse, mutect2
- ZFHX4 | c.8703G>A p.T2901= | Silent (SNP) | VAF 8/46 reads (17%) | catalogued as rs1192176251, COSV51480253; called by muse, mutect2, varscan2
- AC010507.1 | chr19:200767 C>T | 3'Flank (SNP) | VAF 6/51 reads (12%) | catalogued as rs752589210; called by muse, mutect2
- JPH3 | c.2167-1080C>G | Intron (SNP) | VAF 10/70 reads (14%) | called by muse, mutect2, varscan2
